MMRF case MMRF_1452 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6db6472e-a16d-4e85-90c6-dba794bc38d1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.8 years (21,466 days); ISS stage: II; Days to last known disease status: 1,401 days (3.8 years); Days to last follow up: 1,401 days (3.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 83 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days; Days to treatment end: 134 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 177 days; Days to treatment end: 272 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 288 days; Days to treatment end: 291 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 289 days; Days to treatment end: 292 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 291 days; Days to treatment end: 291 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: Second line of therapy; Days to treatment start: 293 days; Days to treatment end: 293 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.073 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.18 mg/dL; Immunoglobulin G 1.8 g/L; Immunoglobulin A 66.6 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 4.54 µg/mL; Lactate Dehydrogenase 1.67 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.55 mmol/L; Albumin 32 g/L; Total Protein 11 g/dL; Glucose 9.19 mmol/L.
- Day 79 (ECOG 1): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.27 mg/dL; Immunoglobulin G 2.07 g/L; Immunoglobulin A 13.2 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 302 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 177 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.2 mg/dL; Immunoglobulin G 2.43 g/L; Immunoglobulin A 33.2 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 8.3 g/dL; Glucose 4.84 mmol/L.
- Day 272 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.202 mg/dL; Immunoglobulin G 1.51 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 5.5 g/dL; Glucose 5.34 mmol/L.
- Day 356 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 6.47 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 10.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 7.26 mmol/L.
- Day 461 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.094 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 2.96 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.45 mmol/L; Albumin 48 g/L; Total Protein 6.6 g/dL; Glucose 7.15 mmol/L.
- Day 544 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.113 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 2.41 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 7.82 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 11 mmol/L.
- Day 645 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.094 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 2.18 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 46 g/L; Total Protein 5.9 g/dL; Glucose 6.16 mmol/L.
- Day 750 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.077 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 8.2 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 47 g/L; Total Protein 6 g/dL; Glucose 5.61 mmol/L.
- Day 841 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 1.01 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 6.2 g/dL; Glucose 6.05 mmol/L.
- Day 932 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0.7 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 46 g/L; Total Protein 6 g/dL; Glucose 6.6 mmol/L.
- Day 1,023 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.274 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0.6 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 1,125 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.097 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0.6 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 1,226 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.094 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0.48 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 47 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.
- Day 1,310 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0.48 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 49 g/L; Total Protein 6.3 g/dL; Glucose 5.72 mmol/L.
- Day 1,401 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.091 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0.41 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 5.8 g/dL; Glucose 6.05 mmol/L.

Other clinical attributes
- Day 1: Weight: 75 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.

Biospecimens (1 sample)
- Sample MMRF_1452_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
